Somatic mutation profile of tumor specimen MMRF_1618_1_BM_CD138pos (aliquot MMRF_1618_1_BM_CD138pos_T2_KHS5U_K14083) from MMRF case MMRF_1618, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.9 years (20,427 days).
Specimen MMRF_1618_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd6f4ca-ae2e-45f2-876f-d86f8da1a809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1618_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1618_1_PB_Whole_C2_KHS5U_K14073; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/520bce32-b4fb-4fe3-b28a-7452a80b309e

The open-access MAF lists 99 somatic variants for this specimen: 40 protein-altering or splice-affecting, 14 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 25, Silent 14, Intron 12, 5'UTR 5, Splice Site 4, 3'Flank 2, Nonsense Mutation 2, Frame Shift Del 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 153/300 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56278125; called by muse, mutect2, varscan2
- CDK8 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 93/98 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV101037639, COSV67420711; called by muse, mutect2, varscan2
- CHRNA2 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.782); catalogued as rs1469021939; called by muse, mutect2, varscan2
- CYP2C8 | c.1324C>G p.R442G | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100987957, COSV64878711; called by muse, mutect2, varscan2
- DSE | c.-53-1G>C | Splice Site (SNP) | VAF 154/398 reads (39%) | catalogued as COSV59066754; called by muse, mutect2, varscan2
- FBN3 | c.5147C>T p.T1716M | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs190008312; called by muse, mutect2, varscan2
- LANCL2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as COSV54651106; called by muse, mutect2, varscan2
- LYZL6 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371856262; called by muse, mutect2, varscan2
- MMRN2 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.817); catalogued as rs757358805, COSV64400320; called by muse, mutect2, varscan2
- NPTX2 | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675040; called by muse, mutect2, varscan2
- PLEKHA5 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs750787132, COSV54695806; called by muse, mutect2, varscan2
- PPP2R3A | c.3329+3_3329+6del p.X1110_splice | Splice Site (DEL) | VAF 44/100 reads (44%) | catalogued as rs769579646; called by mutect2, varscan2
- TEX14 | c.1994C>T p.S665F (on ENST00000240361 / NM_001201457.2; = p.S659F on NM_031272.5) | Missense Mutation (SNP) | VAF 93/159 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99543342; called by muse, mutect2, varscan2
- TIGD3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 134/490 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as rs745393854; called by muse, mutect2, varscan2
- TTC30B | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs1422919051, COSV68809859; called by muse, mutect2, varscan2
- ARAF | c.844A>G p.K282E | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ATP2B3 | c.1861G>C p.G621R | Missense Mutation (SNP) | VAF 332/531 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD40 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by mutect2, varscan2
- CYP26B1 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- DCDC1 | c.4429T>G p.F1477V (on ENST00000597505 / NM_001367979.1; = p.F584V on NM_020869.3) | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DLX3 | c.520A>T p.K174* | Nonsense Mutation (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- DNAH3 | c.1427C>G p.P476R | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ERO1B | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- FLG | c.3937C>A p.Q1313K | Missense Mutation (SNP) | VAF 76/130 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HOXD10 | c.859T>A p.F287I | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KALRN | c.2481G>T p.E827D | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.78); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KCNK18 | c.75C>A p.C25* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- KCNQ3 | c.1874T>G p.V625G | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK11 | c.814G>A p.V272M (on ENST00000594768 / NM_144947.3; = p.V240M on NM_006853.3) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- KLRK1 | c.95_99del p.T32Mfs*14 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- LRCH2 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- MECP2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- NRXN3 | c.320G>A p.S107N | Missense Mutation (SNP) | VAF 147/264 reads (56%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PATL2 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 133/299 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PRSS36 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- RNF43 | c.2342A>C p.Q781P | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- RTF2 | c.647-1G>A p.X216_splice | Splice Site (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- SMAP1 | c.713C>T p.P238L (on ENST00000370455 / NM_001044305.3; = p.P211L on NM_021940.5) | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SP140 | c.489_490+10del p.X163_splice | Splice Site (DEL) | VAF 42/63 reads (67%) | called by mutect2, pindel, varscan2
- VSIG1 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- AHCYL1 | c.879C>T p.C293= | Silent (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- C10orf53 | c.445C>T p.L149= | Silent (SNP) | VAF 169/422 reads (40%) | called by muse, mutect2, varscan2
- CALML5 | c.285C>T p.D95= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs769481400; called by muse, mutect2, varscan2
- FAM171B | c.162A>G p.Q54= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs1559078357; called by muse, mutect2, varscan2
- KIAA2012 | c.327T>G p.L109= | Silent (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- LACTBL1 | c.372C>T p.A124= (on ENST00000618559; = p.A153= on NM_001289974.2) | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as rs759591352, COSV70777344; called by muse, mutect2, varscan2
- MLLT6 | c.57G>A p.E19= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs1200137336; called by muse, mutect2, varscan2
- NBPF3 | c.1512C>T p.F504= | Silent (SNP) | VAF 42/193 reads (22%) | called by muse, mutect2, varscan2
- NPTX2 | c.1002T>C p.T334= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- OR4C16 | c.486G>C p.L162= | Silent (SNP) | VAF 98/310 reads (32%) | catalogued as COSV58943776; called by muse, mutect2, varscan2
- PDE11A | c.498C>A p.P166= | Silent (SNP) | VAF 100/238 reads (42%) | catalogued as rs753913877; called by muse, mutect2, varscan2
- PPFIA3 | c.108C>T p.L36= | Silent (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- RANBP3 | c.870A>C p.A290= (on ENST00000340578 / NM_007322.3; = p.A285= on NM_003624.3) | Silent (SNP) | VAF 50/170 reads (29%) | called by muse, mutect2, varscan2
- TRIML2 | c.885T>C p.A295= | Silent (SNP) | VAF 74/196 reads (38%) | called by muse, mutect2, varscan2
- ABCA8 | c.4079+23T>G | Intron (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- ADGRA3 | c.1809+329dup | Intron (INS) | VAF 26/52 reads (50%) | catalogued as rs1229135243; called by mutect2, varscan2
- ARHGEF10 | c.*768C>G | 3'UTR (SNP) | VAF 39/74 reads (53%) | catalogued as rs1219270592; called by muse, mutect2, varscan2
- CCDC127 | c.-10-268dup | Intron (INS) | VAF 39/88 reads (44%) | called by mutect2, varscan2
- CRHR2 | c.-57C>T | 5'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- DYNC1LI2 | c.*1542C>T | 3'UTR (SNP) | VAF 59/60 reads (98%) | called by muse, mutect2, varscan2
- EDN3 | c.*1037C>A | 3'UTR (SNP) | VAF 86/182 reads (47%) | called by muse, mutect2, varscan2
- EFCAB14 | c.-977C>T | 5'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- FAM200A | c.*277G>A | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- FAM20C | c.864-18481C>G | Intron (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2
- FCGR1B | chr1:121097505 C>T | 3'Flank (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- GABRB2 | c.*3875C>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- GABRP | c.-17G>T | 5'UTR (SNP) | VAF 151/325 reads (46%) | called by muse, mutect2, varscan2
- GALNT7 | c.*589A>G | 3'UTR (SNP) | VAF 42/87 reads (48%) | catalogued as rs763620753; called by muse, mutect2, varscan2
- GATA6 | c.*412C>T | 3'UTR (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- HERC4 | c.226+2707A>G | Intron (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- INHBB | c.*1712G>A | 3'UTR (SNP) | VAF 27/55 reads (49%) | catalogued as rs986314877; called by muse, mutect2, varscan2
- JADE1 | c.*2345C>A | 3'UTR (SNP) | VAF 81/172 reads (47%) | called by muse, mutect2, varscan2
- KRAS | c.*2974del | 3'UTR (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- LMOD2 | c.*337G>T | 3'UTR (SNP) | VAF 53/109 reads (49%) | called by muse, mutect2, varscan2
- LTB | c.163-78G>C | Intron (SNP) | VAF 213/492 reads (43%) | catalogued as COSV53002650; called by muse, varscan2
- LUZP2 | c.*574C>T | 3'UTR (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- MCM7 | c.*55G>C | 3'UTR (SNP) | VAF 40/78 reads (51%) | catalogued as rs1238029410, COSV100384892; called by muse, mutect2, varscan2
- MDFIC | c.-107-64G>A | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- MGST1 | c.*346T>C | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- MMP14 | c.*1074C>T | 3'UTR (SNP) | VAF 123/237 reads (52%) | called by muse, mutect2, varscan2
- MMP8 | c.*1216A>G | 3'UTR (SNP) | VAF 45/142 reads (32%) | catalogued as rs1018145046; called by muse, mutect2, varscan2
- MST1 | c.-266G>A | 5'UTR (SNP) | VAF 57/142 reads (40%) | catalogued as rs1247573631; called by muse, mutect2, varscan2
- NIPA1 | c.*4436C>G | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- OGT | chrX:71530341 G>A | 5'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- PDCL | c.*1619A>T | 3'UTR (SNP) | VAF 74/161 reads (46%) | called by muse, mutect2, varscan2
- PEG3 | c.-86-235G>C | Intron (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- PELI2 | c.*4100A>T | 3'UTR (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4883C>A | Intron (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2853+39T>A | Intron (SNP) | VAF 94/207 reads (45%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.-42C>A | 5'UTR (SNP) | VAF 186/437 reads (43%) | catalogued as COSV59779899; called by muse, mutect2, varscan2
- RBM39 | c.52-389G>A | Intron (SNP) | VAF 47/82 reads (57%) | catalogued as COSV99488406; called by muse, mutect2, varscan2
- RHOQP2 | chr2:131463420 C>A | 3'Flank (SNP) | VAF 143/281 reads (51%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*5250A>C | 3'UTR (SNP) | VAF 36/70 reads (51%) | called by muse, varscan2
- SEMA5A | c.*2225G>T | 3'UTR (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- STEAP2 | c.*2415T>G | 3'UTR (SNP) | VAF 49/107 reads (46%) | called by muse, mutect2, varscan2
- SYNE2 | c.7221+3175C>T | Intron (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- TM4SF4 | c.*626C>T | 3'UTR (SNP) | VAF 19/37 reads (51%) | catalogued as rs1378108927; called by muse, mutect2, varscan2
- TXNDC5 | c.*977C>T | 3'UTR (SNP) | VAF 52/96 reads (54%) | called by muse, mutect2, varscan2
- VPS13A | c.*943C>T | 3'UTR (SNP) | VAF 101/202 reads (50%) | called by muse, mutect2, varscan2
